Somatic mutation profile of tumor specimen TCGA-32-1979-01A (aliquot TCGA-32-1979-01A-01D-1696-08) from TCGA case TCGA-32-1979, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.1 years (25,252 days).
Specimen TCGA-32-1979-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbf689a7-4cf1-4eac-8d7a-cef2cfe1808f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1979-10A (Blood Derived Normal), aliquot TCGA-32-1979-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b29551e7-e05c-4a3b-b65d-2df3535bf0a4

The open-access MAF lists 80 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 19, Frame Shift Del 3, Nonsense Mutation 3, RNA 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP4F22 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770500550, CM1311775, COSV54106836; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.1163G>A p.R388K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV62929767; called by muse, mutect2, varscan2
- ALG10B | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV58142625; called by muse, mutect2, varscan2
- APH1A | c.32T>C p.F11S | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs782078785, COSV52528464; called by muse, mutect2, varscan2
- ARFGEF3 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as rs1445802336, COSV52452100; called by muse, mutect2, varscan2
- ATP13A1 | c.2717del p.G906Afs*29 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | catalogued as COSV99179131; called by mutect2, varscan2
- AZGP1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs370476332; called by muse, mutect2, varscan2
- BAZ2B | c.3569A>G p.Q1190R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV54275068; called by muse, mutect2, varscan2
- BNC2 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66140373; called by muse, mutect2, varscan2
- BRDT | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781291733, COSV62863797; called by muse, mutect2, varscan2
- C21orf58 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.017); catalogued as rs200456158; called by muse, mutect2, varscan2
- C9orf64 | c.699T>A p.S233R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV59032243; called by muse, mutect2, varscan2
- CDH19 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50955415; called by muse, mutect2, varscan2
- CEP128 | c.2593C>T p.R865C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs373994294; called by muse, mutect2, varscan2
- CHST1 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV57322535; called by muse, mutect2, varscan2
- COL4A6 | c.1649T>A p.L550H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.497); catalogued as COSV57860938; called by muse, mutect2
- DEF6 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs764306600, COSV57353079; called by muse, mutect2, varscan2
- DUSP10 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV60456875; called by muse, mutect2
- EGFR | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 144/2098 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51781245; called by muse, mutect2
- EPB41L3 | c.3119T>C p.V1040A | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59447081; called by muse, mutect2, varscan2
- FAM71B | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs752153945, COSV57228020; called by muse, mutect2, varscan2
- FAM83C | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773562212, COSV65582332; called by muse, varscan2
- FRYL | c.6705+2T>G p.X2235_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | catalogued as COSV51942109; called by muse, mutect2
- GABRB2 | c.1513G>A p.V505I (on ENST00000274547; = p.V467I on NM_000813.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.08); catalogued as rs1218503196, COSV50904714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRHL3 | c.1288G>A p.V430I (on ENST00000350501 / NM_198174.3; = p.V435I on NM_021180.3) | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs199801227, COSV52565046; called by muse, mutect2, varscan2
- HCN1 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs35229491, COSV100300654, COSV57498398; ClinVar: likely benign; called by muse, mutect2, varscan2
- HNF4A | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as rs753027685, COSV57380644; called by mutect2, varscan2
- IGF2R | c.5798A>G p.Y1933C | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63627092; called by muse, mutect2, varscan2
- KRTAP1-3 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1224581809, COSV60335819; called by muse, mutect2, varscan2
- LRP4 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101066965; called by muse, mutect2, varscan2
- MC5R | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 114/341 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1485593304, COSV61253907; called by muse, mutect2, varscan2
- MKI67 | c.8775_8776del p.Q2926Nfs*6 | Frame Shift Del (DEL) | VAF 61/189 reads (32%) | catalogued as rs1173089014; called by pindel, varscan2
- MOCS1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.493); catalogued as rs1318933448, COSV51304921; called by muse, mutect2, varscan2
- MYO1A | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769355024, COSV55652399; called by muse, mutect2, varscan2
- NFIX | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV62175972; called by muse, mutect2
- OR4D2 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 61/167 reads (37%) | catalogued as rs148589207; called by muse, mutect2, varscan2
- OR6N2 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs144962739; called by muse, mutect2, varscan2
- OXR1 | c.1677G>T p.L559F (on ENST00000442977 / NM_001198532.1; = p.L558F on NM_018002.3) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760586673, COSV56325735; called by muse, mutect2
- PCDH12 | c.1078C>G p.P360A | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV51520090; called by muse, mutect2, varscan2
- PDE6A | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs547792004, COSV54925395; called by muse, mutect2, varscan2
- PENK | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767796107, COSV59240443; called by muse, mutect2, varscan2
- PGGHG | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs777823440, COSV66887853; called by muse, mutect2, varscan2
- PIK3CA | c.3207A>G p.*1069Wext*4 | Nonstop Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55879699; called by muse, mutect2, varscan2
- POGLUT3 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60211970; called by muse, mutect2, varscan2
- PRKDC | c.3668C>T p.T1223I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs756873491, COSV58046545; called by muse, mutect2, varscan2
- RET | c.1310A>T p.N437I | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV60689031; called by muse, mutect2, varscan2
- SEMG1 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs199672858, COSV54871705, COSV54872099; called by muse, mutect2, varscan2
- SEZ6L2 | c.2348C>T p.T783M (on ENST00000308713 / NM_001114099.3; = p.T713M on NM_012410.4) | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs372252400; called by muse, mutect2, varscan2
- SH3GL3 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs201410848, COSV61054371; called by muse, mutect2, varscan2
- SLC17A8 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs778461278, COSV60122539; called by muse, mutect2, varscan2
- SLFN13 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs371744448; called by muse, mutect2, varscan2
- ST3GAL1 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | PolyPhen benign (0.003); catalogued as COSV60611061; called by muse, mutect2, varscan2
- TCN1 | c.450C>G p.D150E | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV57252543; called by muse, mutect2, varscan2
- TMEM150A | c.145G>C p.A49P (on ENST00000334462 / NM_001031738.3; = p.L18= on NM_153342.3) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV57817539; called by muse, mutect2
- TRAM1L1 | c.1059A>C p.E353D | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.065); catalogued as COSV60291455; called by muse, mutect2, varscan2
- UGT2B28 | c.1550G>A p.W517* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV59431072; called by muse, mutect2, varscan2
- UGT3A2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772287712, COSV56929085; called by muse, mutect2, varscan2
- UNC45A | c.600G>C p.L200F | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV67815997; called by muse, mutect2, varscan2
- UPF1 | c.2123G>A p.R708H (on ENST00000599848 / NM_001297549.2; = p.R697H on NM_002911.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53194462; called by muse, mutect2, varscan2
- ARPC2 | c.374_375del p.F125* | Frame Shift Del (DEL) | VAF 51/164 reads (31%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.5226A>G p.G1742= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV58217126; called by muse, mutect2, varscan2
- CLEC14A | c.501C>T p.N167= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1339205878, COSV60561988; called by muse, mutect2, varscan2
- CNTNAP2 | c.1785C>T p.Y595= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs781574808, COSV62155069; called by muse, mutect2, varscan2
- DCAF12L1 | c.1233C>T p.L411= | Silent (SNP) | VAF 58/174 reads (33%) | catalogued as COSV64421312; called by muse, mutect2, varscan2
- FAM187B | c.570C>T p.S190= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs551881022, COSV61200874; called by muse, mutect2, varscan2
- GPR25 | c.678G>A p.S226= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV58497776; called by muse, mutect2, varscan2
- IKZF1 | c.1164G>A p.A388= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs776169668, COSV58782820; called by muse, mutect2, varscan2
- MYH1 | c.2967G>T p.L989= | Silent (SNP) | VAF 55/168 reads (33%) | catalogued as COSV56845069, COSV99874705; called by muse, mutect2, varscan2
- NIBAN2 | c.1134C>T p.N378= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as rs770588471, COSV64823906; called by muse, mutect2, varscan2
- OR6V1 | c.24C>T p.S8= | Silent (SNP) | VAF 74/265 reads (28%) | catalogued as rs369508746; called by muse, mutect2, varscan2
- P4HA2 | c.861G>A p.R287= | Silent (SNP) | VAF 77/269 reads (29%) | catalogued as rs1014952802, COSV51324068; called by muse, mutect2, varscan2
- RIPK4 | c.2340C>T p.D780= (on ENST00000352483; = p.D732= on NM_020639.3) | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs372475043; called by muse, mutect2, varscan2
- RSPO4 | c.435C>T p.G145= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs201319898, COSV54080900; called by muse, mutect2, varscan2
- RYR1 | c.12423C>T p.N4141= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as COSV62092006; called by muse, mutect2, varscan2
- SCIN | c.1749C>T p.G583= (on ENST00000297029 / NM_001112706.3; = p.G336= on NM_033128.3) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs369378047; called by muse, mutect2, varscan2
- SOS2 | c.1728A>G p.V576= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as COSV53564826; called by muse, mutect2, varscan2
- TKTL2 | c.207C>T p.N69= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs114941835, COSV54917910, COSV54919438; called by muse, mutect2, varscan2
- TOR4A | c.408C>T p.N136= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV62626729; called by muse, mutect2, varscan2
- ZMYM3 | c.1288C>A p.R430= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV58736742; called by muse, mutect2, varscan2
- C1orf220 | n.641G>A | RNA (SNP) | VAF 21/83 reads (25%) | catalogued as rs756909151; called by muse, mutect2, varscan2
